CCDI case PBBUIS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/df0d8a0d-79b5-447b-8351-2a94be423819

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 21.3 years (7,763 days).

Biospecimens (3 samples)
- Sample 0DHV5Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHV64: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHV6D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
